Somatic mutation profile of tumor specimen 0DHMSC from CCDI case PBBUNX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pinealoma; Tissue or organ of origin: Pineal gland; Age at diagnosis: 17.3 years (6,307 days).
Specimen 0DHMSC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8600dd04-e895-46a3-885c-641ef8e13503.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHMLV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/29ea6b50-89e5-44f9-81d1-a79045c8c00e

The open-access MAF lists 24 somatic variants for this specimen: 14 protein-altering or splice-affecting, 6 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 6, Intron 2, Nonsense Mutation 2, 5'UTR 1, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTSH | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 69/492 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs780571910, COSV54985684; called by muse, mutect2, varscan2
- EIF2B2 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 95/749 reads (13%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs1225416670; called by muse, mutect2, varscan2
- ETV3 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 44/884 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.953); catalogued as rs765692496; called by muse, mutect2
- LCORL | c.1075C>T p.R359C | Missense Mutation (SNP) | VAF 42/977 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.093); catalogued as rs1560288300, COSV58835684; called by muse, mutect2
- SCAF4 | c.1012A>G p.M338V | Missense Mutation (SNP) | VAF 167/1372 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs143326359; called by muse, mutect2, varscan2
- TRIM72 | c.169C>T p.Q57* | Nonsense Mutation (SNP) | VAF 16/215 reads (7%) | catalogued as rs1356384611; called by muse, mutect2
- ZBTB46 | c.1729C>T p.P577S | Missense Mutation (SNP) | VAF 161/382 reads (42%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as rs749859657, COSV55512935; called by muse, mutect2, varscan2
- FAM160A1 | c.1409A>G p.D470G | Missense Mutation (SNP) | VAF 28/623 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2
- FAM83F | c.160C>T p.Q54* | Nonsense Mutation (SNP) | VAF 20/213 reads (9%) | called by muse, mutect2
- HTATSF1 | c.1610_1611del p.K537Rfs*6 | Frame Shift Del (DEL) | VAF 318/357 reads (89%) | called by mutect2, varscan2
- PCDHB2 | c.2314A>C p.I772L | Missense Mutation (SNP) | VAF 63/406 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SGSM2 | c.891G>T p.Q297H | Missense Mutation (SNP) | VAF 30/694 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2
- SLC4A9 | c.769A>G p.T257A (on ENST00000507527 / NM_001258428.2; = p.T233A on NM_031467.3) | Missense Mutation (SNP) | VAF 16/424 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.036); called by muse, mutect2
- SPEN | c.4673G>C p.G1558A | Missense Mutation (SNP) | VAF 46/578 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.138); called by muse, mutect2
- ADPRHL1 | c.3084G>A p.P1028= | Silent (SNP) | VAF 16/208 reads (8%) | catalogued as rs551605017; called by muse, mutect2
- FAM184B | c.486C>T p.L162= | Silent (SNP) | VAF 19/409 reads (5%) | called by muse, mutect2
- FFAR1 | c.225G>A p.P75= | Silent (SNP) | VAF 25/206 reads (12%) | catalogued as rs1464423331, COSV50050835; called by muse, mutect2, varscan2
- OR4C16 | c.24T>G p.T8= | Silent (SNP) | VAF 19/454 reads (4%) | catalogued as COSV100113821; called by muse, mutect2
- TTN | c.2766C>T p.R922= (on ENST00000591111; = p.R876= on NM_003319.4) | Silent (SNP) | VAF 40/462 reads (9%) | catalogued as rs372617952; called by muse, mutect2
- UCK2 | c.516C>T p.S172= | Silent (SNP) | VAF 48/265 reads (18%) | catalogued as rs560349718, COSV63314266, COSV63314684; called by muse, mutect2, varscan2
- CCM2L | c.1263+13C>A | Intron (SNP) | VAF 54/452 reads (12%) | catalogued as rs199942214; called by muse, mutect2, varscan2
- EML3 | c.1363-68C>T | Intron (SNP) | VAF 26/103 reads (25%) | called by muse, mutect2, varscan2
- MROH8 | chr20:37160154 G>A | 5'Flank (SNP) | VAF 52/460 reads (11%) | catalogued as rs867614420; called by muse, varscan2
- NUDCD1 | c.-68G>C | 5'UTR (SNP) | VAF 8/57 reads (14%) | called by muse, mutect2, varscan2
